Somatic mutation profile of tumor specimen TARGET-50-PAKECR-01A (aliquot TARGET-50-PAKECR-01A-01D) from TARGET case TARGET-50-PAKECR, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: female; Vital status: Alive; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 3.0 years (1,102 days).
Specimen TARGET-50-PAKECR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b6330dbc-5add-4c89-a44d-f944d17e0816.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PAKECR-10A (Blood Derived Normal), aliquot TARGET-50-PAKECR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf13bd59-187d-4865-91bf-be9ad6e11641

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL3A1 | c.2054C>T p.P685L | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV58596042; called by muse, mutect2, varscan2
- DNAH6 | c.1449G>A p.W483* | Nonsense Mutation (SNP) | VAF 16/440 reads (4%) | catalogued as COSV52849839; called by muse, mutect2
- INO80 | c.2026C>T p.R676W | Missense Mutation (SNP) | VAF 19/400 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1481604755; called by muse, mutect2
- LATS2 | c.2373C>A p.D791E | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66874813; called by muse, mutect2
- CFTR | c.2209T>C p.S737P | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNPC3 | c.864G>T p.M288I | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- SLC1A7 | c.623T>C p.V208A | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2
- MED14 | c.4035C>T p.S1345= | Silent (SNP) | VAF 33/325 reads (10%) | catalogued as rs757242771, COSV61358508; called by muse, mutect2
- SARM1 | c.2127A>T p.A709= | Silent (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
